Somatic mutation profile of tumor specimen HCM-BROD-0873-C43-01A (aliquot HCM-BROD-0873-C43-01A-11D-A881-36) from HCMI case HCM-BROD-0873-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 66.8 years (24,401 days).
Specimen HCM-BROD-0873-C43-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6df7945-57df-4558-a494-35d62c726742.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0873-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0873-C43-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98da1bc0-419e-4de2-b9df-70d578440918

The open-access MAF lists 547 somatic variants for this specimen: 345 protein-altering or splice-affecting, 180 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 315, Silent 180, Nonsense Mutation 18, Intron 15, Splice Region 5, Splice Site 3, Frame Shift Del 3, 5'Flank 2, 3'UTR 2, 3'Flank 2, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 142/532 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs796052065, CM154496; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 266/557 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs771100656; called by muse, mutect2, varscan2
- ABCB5 | c.3577G>T p.V1193L (on ENST00000404938 / NM_001163941.2; = p.V748L on NM_178559.6) | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as rs745507733; called by muse, mutect2, varscan2
- ACSM2B | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 86/688 reads (13%) | catalogued as rs370210894; called by muse, mutect2, varscan2
- ADAMTS13 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 247/474 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs587701622, COSV63020852; called by muse, mutect2, varscan2
- ADGRF4 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 210/453 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51952806; called by muse, mutect2, varscan2
- AGXT | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 164/499 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as CM970066; called by muse, mutect2, varscan2
- AHR | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 149/484 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1348476694; called by muse, mutect2, varscan2
- AKAP4 | c.445A>G p.R149G | Missense Mutation (SNP) | VAF 202/311 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV62074090; called by muse, mutect2, varscan2
- AOC1 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 226/618 reads (37%) | catalogued as rs1022684348; called by muse, mutect2, varscan2
- APBB1IP | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1239954436, COSV66132958; called by muse, mutect2, varscan2
- APOB | c.4162C>T p.R1388C | Missense Mutation (SNP) | VAF 143/484 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs267599185, COSV51928488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOH | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 164/506 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1034195006; called by muse, mutect2, varscan2
- ASIC5 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72232548; called by muse, mutect2, varscan2
- BATF3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 367/777 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767493633; called by muse, mutect2, varscan2
- BNC1 | c.2556G>T p.E852D | Missense Mutation (SNP) | VAF 248/705 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61757787; called by muse, mutect2, varscan2
- C10orf71 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 143/396 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1271167930; called by muse, mutect2, varscan2
- C10orf71 | c.4070C>A p.A1357E | Missense Mutation (SNP) | VAF 158/708 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as COSV60505808; called by mutect2, varscan2
- C3 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 236/646 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV55571730; called by muse, mutect2, varscan2
- CACNA1E | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751409680, COSV62405324; called by muse, mutect2, varscan2
- CCDC144A | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV60698016; called by muse, mutect2, varscan2
- CCR2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 175/521 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as rs1391405321; called by muse, mutect2, varscan2
- CDH22 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 268/809 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1226830817; called by muse, mutect2, varscan2
- CEP131 | c.1612G>A p.E538K (on ENST00000269392 / NM_001319228.2; = p.E535K on NM_014984.4) | Missense Mutation (SNP) | VAF 168/525 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369438843; called by muse, mutect2, varscan2
- CHP2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs756478431, COSV55649342; called by muse, mutect2, varscan2
- CNTN6 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV63167473, COSV63185871; called by muse, mutect2, varscan2
- COL18A1 | c.2845C>T p.P949S (on ENST00000359759 / NM_130444.3; = p.P714S on NM_030582.4) | Missense Mutation (SNP) | VAF 90/441 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1450327303, COSV62702320; called by muse, mutect2, varscan2
- CSMD1 | c.10448G>A p.G3483D (on ENST00000520002; = p.G3482D on NM_033225.6) | Missense Mutation (SNP) | VAF 177/510 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1429750842, COSV100151116; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 114/440 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, varscan2
- CTAGE1 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 158/338 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs560589174; called by muse, mutect2, varscan2
- CYTIP | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99938946; called by muse, mutect2, varscan2
- DDX23 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 78/436 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV57282909; called by muse, mutect2, varscan2
- DIP2B | c.1342T>C p.F448L | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV56584261; called by muse, mutect2, varscan2
- DNAH14 | c.4520G>A p.R1507Q (on ENST00000445597; = p.R1912Q on NM_001367479.1) | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775576952, COSV60736715; called by muse, mutect2, varscan2
- DNAH7 | c.10496C>T p.T3499I | Missense Mutation (SNP) | VAF 100/335 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as rs751299449; called by muse, mutect2, varscan2
- DNAH7 | c.6971G>A p.S2324N | Missense Mutation (SNP) | VAF 143/505 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs992819121; called by muse, mutect2, varscan2
- DOCK9 | c.2977C>T p.H993Y (on ENST00000376460 / NM_001366676.2; = p.H994Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/412 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV59620841; called by muse, mutect2, varscan2
- EEF1D | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 280/755 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs1414453778; called by muse, mutect2, varscan2
- EFCAB12 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 183/591 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58177472; called by muse, mutect2, varscan2
- EFHB | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 167/529 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs201173584; called by muse, mutect2, varscan2
- EHMT2 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 637/1350 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.125); catalogued as rs777077739; called by muse, mutect2, varscan2
- ERC2 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV55640574; called by muse, mutect2, varscan2
- ERV3-1 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV51428219; called by muse, mutect2, varscan2
- FAIM | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs574122735, COSV100623853, COSV58159054; called by muse, mutect2, varscan2
- FAP | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 129/463 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.856); catalogued as rs756858958, COSV51860211; called by muse, mutect2, varscan2
- FCRL3 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 60/415 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV63840587; called by muse, mutect2, varscan2
- FREM3 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 146/543 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV61682266; called by muse, mutect2, varscan2
- FSIP2 | c.17320C>T p.Q5774* | Nonsense Mutation (SNP) | VAF 91/255 reads (36%) | catalogued as rs374937631; called by muse, mutect2, varscan2
- GBX2 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 255/885 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1389171569; called by muse, mutect2, varscan2
- GDE1 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 137/354 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752547994, COSV62060100; called by muse, mutect2, varscan2
- GDF10 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 308/956 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555207505; called by muse, mutect2, varscan2
- GPR33 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 169/553 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320364399; called by muse, mutect2, varscan2
- GUCY2D | c.2441C>T p.T814M | Missense Mutation (SNP) | VAF 59/470 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.409); catalogued as rs150742659; called by muse, mutect2, varscan2
- HECW2 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 264/828 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770650499; called by muse, mutect2, varscan2
- HPD | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.17); catalogued as rs202129288, COSV100000180; called by muse, mutect2, varscan2
- IBSP | c.38T>C p.M13T | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs570577755; called by muse, mutect2, varscan2
- IDO1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs370075063, COSV99503510; called by muse, mutect2, varscan2
- IQGAP3 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 110/640 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1314320250; called by muse, mutect2, varscan2
- ITGA8 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65232864; called by muse, mutect2, varscan2
- IZUMO2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 118/335 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.391); catalogued as rs761925935, COSV53229350; called by muse, mutect2, varscan2
- KASH5 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 227/661 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV71358055; called by muse, mutect2, varscan2
- KCNK10 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 215/594 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.901); catalogued as rs763733103, COSV56647485; called by muse, mutect2, varscan2
- KIAA1217 | c.3034G>A p.G1012S | Missense Mutation (SNP) | VAF 93/420 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV56814180, COSV56818203; called by muse, mutect2, varscan2
- KIAA2012 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 91/329 reads (28%) | SIFT tolerated (0.32); catalogued as rs760066148; called by muse, mutect2, varscan2
- KIF17 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 215/564 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs756978243; called by muse, mutect2, varscan2
- KRTAP10-3 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 146/845 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.543); catalogued as rs782524222; called by muse, mutect2, varscan2
- LASP1 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 136/464 reads (29%) | catalogued as rs1482520945; called by muse, mutect2, varscan2
- LMOD1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 371/743 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV66173098; called by muse, mutect2, varscan2
- LMOD3 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 140/432 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV101341996; called by muse, mutect2, varscan2
- LPIN3 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 139/486 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs747237851, COSV64718247; called by muse, mutect2, varscan2
- LRPPRC | c.3854C>T p.P1285L | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs373042003, COSV99580007; called by muse, mutect2, varscan2
- LRRK1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 188/609 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1436826237, COSV52615503; called by muse, mutect2, varscan2
- MAD1L1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 283/881 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs201944036; called by muse, mutect2, varscan2
- MAGEA3 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 220/322 reads (68%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV64755890; called by muse, mutect2, varscan2
- MATN1 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 143/394 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs781588451; called by muse, mutect2, varscan2
- MEOX1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 249/789 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.225); catalogued as rs368570481; called by muse, mutect2, varscan2
- MFGE8 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 151/494 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769108892, COSV51555444, COSV99183935; called by muse, mutect2, varscan2
- MLIP | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 364/791 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1178590734, COSV51430243; called by muse, mutect2, varscan2
- MOV10L1 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 244/742 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1024306111; called by muse, mutect2, varscan2
- MROH2B | c.3905G>A p.R1302Q | Missense Mutation (SNP) | VAF 176/385 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as rs549101906, COSV68184289; called by muse, mutect2, varscan2
- MRPL53 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 168/484 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs779401249, COSV99252030; called by muse, mutect2, varscan2
- MSH4 | c.1428G>A p.M476I | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1013691306; called by muse, mutect2, varscan2
- MUC16 | c.17551C>T p.P5851S | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs267605800, COSV67460962; called by muse, mutect2, varscan2
- MUC4 | c.13378C>T p.P4460S (on ENST00000463781 / NM_018406.7; = p.P224S on NM_004532.6) | Missense Mutation (SNP) | VAF 204/658 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV57789476; called by muse, mutect2, varscan2
- MUC4 | c.10276C>T p.P3426S | Missense Mutation (SNP) | VAF 171/1432 reads (12%) | SIFT tolerated, low confidence (0.74); PolyPhen possibly damaging (0.65); catalogued as COSV57769062; called by muse, mutect2, varscan2
- MYF5 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99953293; called by muse, mutect2, varscan2
- MYH4 | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 211/631 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs780917874, COSV55113885; called by muse, mutect2, varscan2
- MYO1F | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 264/916 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs201646155, COSV57791852; called by muse, mutect2, varscan2
- MYOCD | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 163/550 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1051971711, COSV100591711; called by muse, mutect2, varscan2
- MYOCD | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 203/572 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1567605374; called by muse, mutect2, varscan2
- MYOM2 | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 163/486 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100037474; called by muse, mutect2, varscan2
- MYRIP | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 275/828 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56884749; called by muse, mutect2, varscan2
- NALCN | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 93/355 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.155); catalogued as rs773688637, COSV99216290; called by muse, mutect2, varscan2
- NDST4 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52126935; called by muse, mutect2, varscan2
- NEU4 | c.1099C>T p.P367S (on ENST00000391969 / NM_001167602.3; = p.P379S on NM_080741.4) | Missense Mutation (SNP) | VAF 390/1252 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs776323817; called by muse, mutect2, varscan2
- NLRP11 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 108/354 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs866104256, COSV64086222; called by muse, mutect2, varscan2
- NLRP2 | c.1331G>C p.R444P | Missense Mutation (SNP) | VAF 333/1045 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99672146; called by muse, mutect2, varscan2
- NLRX1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs775689434, COSV52703240; called by muse, mutect2, varscan2
- NPAS3 | c.331G>A p.D111N (on ENST00000356141 / NM_001164749.2; = p.D81N on NM_022123.3) | Missense Mutation (SNP) | VAF 83/500 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs201385420, COSV58075899, COSV58105393; called by muse, mutect2, varscan2
- NUP188 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 179/351 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1003233120; called by muse, mutect2, varscan2
- NUTM1 | c.2794G>A p.G932R | Missense Mutation (SNP) | VAF 196/554 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs1353793989; called by muse, mutect2, varscan2
- NUTM1 | c.2795G>A p.G932E | Missense Mutation (SNP) | VAF 195/553 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.563); catalogued as COSV100149121; called by muse, mutect2, varscan2
- OR10G9 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100901760; called by muse, mutect2
- OR7G2 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 156/535 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1407211337; called by muse, mutect2
- OR8B4 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV62070052, COSV62070546; called by muse, mutect2, varscan2
- OR9A4 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 82/407 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs535851431, COSV71885566, COSV71886048; called by muse, mutect2, varscan2
- PCIF1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 173/544 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750052866, COSV65026518; called by muse, mutect2, varscan2
- PGF | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 238/691 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs777134198; called by muse, mutect2, varscan2
- PLIN4 | c.334G>A p.D112N (on ENST00000301286; = p.D127N on NM_001367868.2) | Missense Mutation (SNP) | VAF 236/714 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.674); catalogued as rs765437785; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as COSV62610678; called by muse, mutect2, varscan2
- PZP | c.3179C>T p.S1060F | Missense Mutation (SNP) | VAF 151/415 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.722); catalogued as rs914246288; called by muse, varscan2
- RANBP10 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 193/486 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs867080632, COSV58160384, COSV58161287; called by muse, mutect2, varscan2
- RASAL1 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 131/387 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55655873; called by muse, mutect2, varscan2
- RBM20 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 141/575 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750763255, COSV65702985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNASE4 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 170/565 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs374269522, COSV59011986; called by muse, mutect2, varscan2
- RNPS1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 185/493 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.968); catalogued as rs1191835522; called by muse, mutect2, varscan2
- RPRD2 | c.3823C>T p.P1275S | Missense Mutation (SNP) | VAF 375/797 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as rs747479817; called by muse, mutect2, varscan2
- SAMD9L | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV59080462, COSV59082718; called by muse, mutect2, varscan2
- SBF1 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 261/872 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62367508; called by muse, mutect2, varscan2
- SCFD2 | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 84/296 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66371492; called by muse, mutect2, varscan2
- SCN4A | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 240/736 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs886053249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINB4 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868227362, COSV61984277; called by muse, mutect2, varscan2
- SEZ6L | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 215/714 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as rs765777882; called by muse, mutect2, varscan2
- SH3D19 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 121/499 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381746635, COSV58792461; called by muse, mutect2, varscan2
- SHANK2 | c.5105C>T p.S1702L | Missense Mutation (SNP) | VAF 34/595 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.423); catalogued as rs1555149232, COSV53594516; called by muse, mutect2
- SLC7A10 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 171/535 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53504027; called by muse, mutect2, varscan2
- SLC8A2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 290/999 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs574343557, COSV52643358; called by muse, mutect2, varscan2
- SLC9C2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs1010780200; called by muse, mutect2, varscan2
- SORL1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 103/289 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52762503; called by muse, mutect2, varscan2
- SORL1 | c.4969C>T p.L1657F | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1482327766; called by muse, mutect2, varscan2
- SPEG | c.8540G>A p.R2847Q | Missense Mutation (SNP) | VAF 244/752 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs560447047, COSV56669202; called by muse, mutect2, varscan2
- SRGAP3 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 241/795 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1226323955, COSV64533200; called by muse, mutect2, varscan2
- STAB2 | c.6119C>T p.S2040L | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1327618835, COSV66337547; called by muse, mutect2, varscan2
- TARS2 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 351/693 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201039460; called by muse, mutect2, varscan2
- TDO2 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 101/308 reads (33%) | catalogued as rs530115805; called by muse, mutect2, varscan2
- TET2 | c.5437C>T p.Q1813* | Nonsense Mutation (SNP) | VAF 155/491 reads (32%) | catalogued as rs1315434367; called by muse, mutect2, varscan2
- TLL1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1452918005, COSV50269380; called by muse, mutect2, varscan2
- TNFSF14 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 226/574 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs879722620; called by muse, mutect2
- TRMT1L | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1214873274; called by muse, mutect2, varscan2
- TRPC4 | c.2771G>A p.G924E (on ENST00000379705 / NM_016179.4; = p.G929E on NM_003306.3) | Missense Mutation (SNP) | VAF 112/326 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58999192, COSV59001644; called by muse, mutect2, varscan2
- TRPV1 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 145/486 reads (30%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs201663686; called by muse, mutect2, varscan2
- VCL | c.3391C>T p.P1131S (on ENST00000211998 / NM_014000.3; = p.P1063S on NM_003373.4) | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1226232250; called by muse, mutect2, varscan2
- WASL | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV56136484; called by muse, mutect2, varscan2
- WDR64 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 281/544 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs759519562; called by muse, mutect2, varscan2
- WDTC1 | c.1343A>G p.Y448C (on ENST00000319394 / NM_001276252.2; = p.Y447C on NM_015023.5) | Missense Mutation (SNP) | VAF 103/542 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs747760786, COSV60088691; called by muse, mutect2, varscan2
- WNT4 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 133/362 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as rs1257786771; called by muse, mutect2, varscan2
- XPO1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 76/296 reads (26%) | catalogued as COSV99065710; called by muse, varscan2
- ZBTB14 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 188/472 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767606188, COSV63696300; called by muse, mutect2, varscan2
- ZDHHC19 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200886120, COSV99579642; called by muse, mutect2, varscan2
- ZG16B | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 234/570 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.412); catalogued as rs751882900, COSV66525872; called by muse, mutect2, varscan2
- ZHX2 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 249/850 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV58717163; called by muse, mutect2
- ZNF217 | c.2942C>T p.P981L | Missense Mutation (SNP) | VAF 152/589 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1021240005, COSV56602931; called by muse, mutect2, varscan2
- ZNF474 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV56946764; called by muse, mutect2, varscan2
- ZNF568 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 210/668 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs778837491, COSV71278977; called by muse, mutect2, varscan2
- ZNF726 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.648); catalogued as rs1243180625, COSV58044217; called by muse, mutect2, varscan2
- ZSCAN30 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV104412100; called by muse, mutect2, varscan2
- ABCA3 | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 116/675 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA7 | c.2551C>T p.L851= | Splice Region (SNP) | VAF 142/440 reads (32%) | called by muse, varscan2
- ABCC6 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 183/476 reads (38%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- ACSM2A | c.1369C>T p.Q457* (on ENST00000219054; = p.Q378* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 78/208 reads (38%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.3365del p.N1122Tfs*3 | Frame Shift Del (DEL) | VAF 161/483 reads (33%) | called by mutect2, pindel, varscan2
- ADAR | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 218/417 reads (52%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL1 | c.3059G>A p.G1020D | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2
- AHNAK | c.7687A>T p.K2563* | Nonsense Mutation (SNP) | VAF 165/412 reads (40%) | called by muse, mutect2, varscan2
- AHNAK2 | c.16115A>G p.N5372S | Missense Mutation (SNP) | VAF 178/531 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AK9 | c.4555G>A p.V1519I | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALDOB | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 157/344 reads (46%) | called by muse, mutect2, varscan2
- ANKRD12 | c.5929G>T p.V1977L | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANKRD2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARC | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 184/703 reads (26%) | called by muse, mutect2, varscan2
- ATAD5 | c.4331C>T p.T1444I | Missense Mutation (SNP) | VAF 110/427 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ATP13A2 | c.3427C>T p.P1143S | Missense Mutation (SNP) | VAF 235/646 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- B3GALT1 | c.469T>A p.L157I | Missense Mutation (SNP) | VAF 200/580 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- BBS9 | c.2149C>T p.Q717* (on ENST00000242067 / NM_001348036.1; = p.Q677* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 168/505 reads (33%) | called by muse, mutect2, varscan2
- BRCA2 | c.10109G>A p.R3370K | Missense Mutation (SNP) | VAF 151/392 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BRSK1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 229/839 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- C19orf18 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 142/447 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3orf56 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 200/545 reads (37%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- C5orf34 | c.1459T>C p.F487L | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CCR5 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 216/641 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- CDH13 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDHR5 | c.261G>A p.E87= | Splice Region (SNP) | VAF 180/420 reads (43%) | called by muse, mutect2, varscan2
- CDK10 | c.884C>T p.A295V (on ENST00000353379 / NM_052988.5; = p.A224V on NM_052987.4) | Missense Mutation (SNP) | VAF 220/604 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CDKN2D | c.144C>T p.V48= | Splice Region (SNP) | VAF 127/390 reads (33%) | called by muse, mutect2, varscan2
- CEP250 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 247/682 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- CFAP221 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 121/384 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP47 | c.7525C>T p.Q2509* | Nonsense Mutation (SNP) | VAF 91/134 reads (68%) | called by muse, mutect2, varscan2
- CFAP54 | c.8383G>T p.D2795Y | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CFAP54 | c.8656G>A p.D2886N | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CNGA3 | c.1755G>A p.M585I | Missense Mutation (SNP) | VAF 197/631 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CNN3 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 127/380 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL12A1 | c.3134C>T p.P1045L | Missense Mutation (SNP) | VAF 16/584 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2
- COL5A1 | c.3539G>A p.G1180E | Missense Mutation (SNP) | VAF 177/345 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL5A3 | c.3400G>A p.D1134N | Missense Mutation (SNP) | VAF 274/818 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- COL6A6 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 234/758 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- COL9A3 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 299/922 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX7B | c.143_159del p.F48Yfs*44 | Frame Shift Del (DEL) | VAF 88/161 reads (55%) | called by mutect2, pindel, varscan2
- CRLF3 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 134/475 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- CSMD1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CSMD2 | c.3287-1G>A p.X1096_splice | Splice Site (SNP) | VAF 112/606 reads (18%) | called by muse, mutect2, varscan2
- CTAGE8 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 73/489 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- DHX57 | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 170/543 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLC1 | c.2941C>T p.P981S (on ENST00000276297 / NM_001348081.2; = p.P544S on NM_006094.5) | Missense Mutation (SNP) | VAF 172/572 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNHD1 | c.9604C>T p.L3202F | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ECE1 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 174/457 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- EIF2AK4 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 120/393 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- EIF2S3B | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 132/690 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FAM151A | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 78/414 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 217/383 reads (57%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- FOXA1 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 179/670 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FREM2 | c.4390C>T p.P1464S | Missense Mutation (SNP) | VAF 169/569 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRYL | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 86/344 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- GLB1L | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 206/732 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNA15 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 194/504 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA3 | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 154/824 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR45 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 243/809 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- GRID2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAVCR1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 115/246 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- HCRTR2 | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 161/645 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- HERC1 | c.6541G>A p.G2181R | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPB11 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IDO1 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFNL2 | c.195A>T p.E65D | Missense Mutation (SNP) | VAF 142/408 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV4-28 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 154/558 reads (28%) | called by muse, mutect2
- IGLV8-61 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 176/471 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQGAP3 | c.4569C>T p.S1523= | Splice Region (SNP) | VAF 69/364 reads (19%) | called by muse, mutect2, varscan2
- ITIH2 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- ITPR3 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 283/606 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAG2 | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 200/582 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- KAT6B | c.895T>C p.C299R | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM4F | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLF3 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 154/440 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- KNTC1 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- KRR1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT4 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LCT | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 118/409 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGI1 | c.1487A>T p.Y496F | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- LILRA2 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 155/523 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- LIPJ | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 77/394 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- LRFN5 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 141/419 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- LRRIQ3 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LTBP1 | c.2806G>A p.G936R (on ENST00000404816 / NM_206943.4; = p.G610R on NM_000627.4) | Missense Mutation (SNP) | VAF 126/391 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LTK | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 223/711 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAP4K1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 209/655 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP4K1 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 209/659 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAPKBP1 | c.2057C>T p.S686F (on ENST00000456763 / NM_001128608.2; = p.S680F on NM_014994.3) | Missense Mutation (SNP) | VAF 166/562 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MBOAT4 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 156/441 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCHR2 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MED14 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 100/146 reads (68%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MED24 | c.2446T>G p.C816G | Missense Mutation (SNP) | VAF 152/505 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMRN2 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 164/609 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.27601C>T p.P9201S | Missense Mutation (SNP) | VAF 204/729 reads (28%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.058); called by muse, mutect2
- MUC16 | c.3785C>T p.P1262L | Missense Mutation (SNP) | VAF 234/747 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- MUC7 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 228/888 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.093); called by muse, varscan2
- MYH6 | c.3425C>T p.S1142F | Missense Mutation (SNP) | VAF 190/796 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- NCKAP5 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 149/448 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NEIL3 | c.453A>C p.K151N | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NFRKB | c.3774G>A p.Q1258= (on ENST00000446488 / NM_001143835.2; = p.Q1283= on NM_006165.3) | Splice Region (SNP) | VAF 45/294 reads (15%) | called by muse, mutect2, varscan2
- NISCH | c.2149C>T p.H717Y | Missense Mutation (SNP) | VAF 288/943 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NIT2 | c.571del p.L191Ffs*35 | Frame Shift Del (DEL) | VAF 124/409 reads (30%) | called by mutect2, pindel, varscan2
- NLRP1 | c.4036T>G p.W1346G (on ENST00000572272 / NM_033004.4; = p.W1302G on NM_014922.5) | Missense Mutation (SNP) | VAF 135/469 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOC3L | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, varscan2
- NONO | c.368A>T p.E123V | Missense Mutation (SNP) | VAF 190/303 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OGDHL | c.2306G>A p.G769D | Missense Mutation (SNP) | VAF 103/346 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPRPN | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 153/598 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- OR10J1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 276/546 reads (51%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5B12 | c.721T>G p.S241A | Missense Mutation (SNP) | VAF 131/304 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- OR8S1 | c.920T>C p.L307S | Missense Mutation (SNP) | VAF 191/448 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- OS9 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOGL | c.1462G>A p.D488N (on ENST00000547103; = p.D479N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PABPC1L | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 222/629 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- PALM3 | c.484G>A p.D162N (on ENST00000340790; = p.D177N on NM_001145028.2) | Missense Mutation (SNP) | VAF 204/737 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PCDHA7 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PCNT | c.8522C>T p.A2841V | Missense Mutation (SNP) | VAF 211/506 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDE3A | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 112/251 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PDGFRA | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 98/399 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGPEP1L | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 168/506 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PKDREJ | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 126/434 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLCB1 | c.2494C>G p.L832V | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PLIN5 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 303/936 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PLXNA2 | c.3185C>A p.T1062K | Missense Mutation (SNP) | VAF 194/457 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- PLXNA2 | c.3184A>T p.T1062S | Missense Mutation (SNP) | VAF 193/454 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PLXNA4 | c.4207G>A p.D1403N | Missense Mutation (SNP) | VAF 230/534 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- POTEF | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 64/1176 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2
- POTEJ | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 107/810 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRADC1 | c.22T>C p.W8R | Missense Mutation (SNP) | VAF 196/639 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); called by muse, mutect2
- PRR36 | c.2854C>T p.L952F | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PRR36 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 312/1035 reads (30%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- RAB44 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 203/807 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- RAD23A | c.701T>C p.F234S | Missense Mutation (SNP) | VAF 283/751 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RASAL2 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 56/563 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- RASGRF1 | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 261/784 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM19 | c.1152G>A p.W384* | Nonsense Mutation (SNP) | VAF 166/451 reads (37%) | called by muse, mutect2, varscan2
- RBM19 | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 168/455 reads (37%) | called by muse, mutect2, varscan2
- REXO1 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 236/680 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, varscan2
- RGPD4 | c.4930C>T p.P1644S | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIC8B | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 79/520 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- RNF11 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- RNF112 | c.1133A>T p.D378V | Missense Mutation (SNP) | VAF 132/455 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- RPS2 | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 166/447 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- RUNX1T1 | c.740+1G>A p.X247_splice (on ENST00000265814 / NM_001198628.1; = p.X220_splice on NM_004349.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 109/344 reads (32%) | called by muse, mutect2, varscan2
- SCART1 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 16/585 reads (3%) | SIFT tolerated (0.73); PolyPhen benign (0.023); called by muse, mutect2
- SCUBE3 | c.2416G>A p.G806R | Missense Mutation (SNP) | VAF 232/511 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCUBE3 | c.2417G>A p.G806E | Missense Mutation (SNP) | VAF 235/517 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDAD1 | c.640T>G p.L214V | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SERINC3 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 19/664 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH2D3A | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 261/746 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHLD2 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 29/164 reads (18%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 222/793 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLC6A14 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 96/150 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SLC6A20 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 111/343 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SLC9A2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 178/508 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SMARCC2 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNRPF | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SORL1 | c.6449G>A p.S2150N | Missense Mutation (SNP) | VAF 56/418 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPEM1 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 222/692 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- SWAP70 | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TCN1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TENM2 | c.2255G>A p.G752E (on ENST00000518659 / NM_001122679.2; = p.G520E on NM_001080428.3) | Missense Mutation (SNP) | VAF 199/400 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TEX11 | c.251G>A p.G84E (on ENST00000344304; = p.G69E on NM_031276.3) | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TMC5 | c.2218G>A p.D740N (on ENST00000396229 / NM_001105248.1; = p.D494N on NM_024780.5) | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TMEM131 | c.4223C>T p.P1408L | Missense Mutation (SNP) | VAF 228/765 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM265 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 130/639 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TNKS | c.3676T>A p.Y1226N | Missense Mutation (SNP) | VAF 185/551 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOM1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 17/480 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2
- TOM1L2 | c.782T>A p.L261H (on ENST00000379504 / NM_001350333.2; = p.L211H on NM_001033551.3) | Missense Mutation (SNP) | VAF 117/419 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRA2B | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 150/446 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TRIM42 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 230/724 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TTC3 | c.1444-1G>A p.X482_splice | Splice Site (SNP) | VAF 36/207 reads (17%) | called by muse, mutect2, varscan2
- UBASH3A | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 188/462 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- UGT2B17 | c.374T>G p.I125R | Missense Mutation (SNP) | VAF 64/103 reads (62%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC80 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 184/578 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VANGL2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 109/682 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- VWF | c.5450C>T p.S1817F | Missense Mutation (SNP) | VAF 120/314 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- WDR45 | c.298A>G p.T100A (on ENST00000376372 / NM_001029896.2; = p.T101A on NM_007075.3) | Missense Mutation (SNP) | VAF 253/370 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- WDR7 | c.4464C>A p.F1488L | Missense Mutation (SNP) | VAF 78/425 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- WDR70 | c.1637G>A p.S546N | Missense Mutation (SNP) | VAF 148/334 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WFIKKN2 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 166/450 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP1 | c.4727G>A p.G1576E | Missense Mutation (SNP) | VAF 243/781 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZBTB8B | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 117/618 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF19 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 67/387 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZNF235 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 160/561 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF536 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 294/929 reads (32%) | called by muse, mutect2, varscan2
- ZNF707 | c.700T>G p.C234G | Missense Mutation (SNP) | VAF 443/1299 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC099489.1 | c.2298G>A p.G766= | Silent (SNP) | VAF 252/684 reads (37%) | catalogued as rs932302222; called by muse, mutect2
- ACE2 | c.768C>T p.I256= | Silent (SNP) | VAF 122/185 reads (66%) | catalogued as rs377035576, COSV53026275; called by muse, mutect2, varscan2
- AGBL1 | c.2832C>T p.I944= | Silent (SNP) | VAF 99/296 reads (33%) | catalogued as COSV66853788; called by muse, mutect2, varscan2
- AGXT | c.876C>T p.R292= | Silent (SNP) | VAF 209/717 reads (29%) | catalogued as rs763852365, COSV56755607; called by muse, mutect2, varscan2
- AL645922.1 | c.2031G>A p.R677= | Silent (SNP) | VAF 286/1194 reads (24%) | called by muse, mutect2, varscan2
- AL662899.2 | c.264C>T p.I88= | Silent (SNP) | VAF 218/945 reads (23%) | catalogued as COSV65508262; called by muse, mutect2, varscan2
- ANKRD34C | c.615G>A p.K205= | Silent (SNP) | VAF 197/562 reads (35%) | called by muse, mutect2, varscan2
- APOB | c.4680C>T p.S1560= | Silent (SNP) | VAF 112/431 reads (26%) | catalogued as rs948486350, COSV51938869; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARC | c.1155C>T p.S385= | Silent (SNP) | VAF 186/715 reads (26%) | catalogued as rs767852123; called by muse, mutect2, varscan2
- ARFGEF1 | c.2083C>T p.L695= | Silent (SNP) | VAF 98/317 reads (31%) | catalogued as rs773815622; called by muse, mutect2, varscan2
- ARHGAP17 | c.138C>T p.S46= | Silent (SNP) | VAF 191/508 reads (38%) | catalogued as COSV99253306; called by muse, mutect2, varscan2
- BEND4 | c.588C>T p.S196= | Silent (SNP) | VAF 129/492 reads (26%) | called by muse, varscan2
- BOLA3 | c.315C>T p.P105= | Silent (SNP) | VAF 229/638 reads (36%) | called by muse, mutect2, varscan2
- CA13 | c.468C>T p.S156= | Silent (SNP) | VAF 59/196 reads (30%) | catalogued as rs368124926; called by muse, mutect2, varscan2
- CACNA1H | c.4611C>T p.S1537= | Silent (SNP) | VAF 186/525 reads (35%) | catalogued as rs909891273, COSV61995498; called by muse, mutect2, varscan2
- CACNA2D1 | c.432G>A p.R144= | Silent (SNP) | VAF 51/308 reads (17%) | called by muse, mutect2, varscan2
- CARD10 | c.1458G>C p.L486= | Silent (SNP) | VAF 194/689 reads (28%) | called by muse, mutect2, varscan2
- CASP2 | c.597T>C p.R199= | Silent (SNP) | VAF 84/409 reads (21%) | called by muse, mutect2, varscan2
- CCDC40 | c.792C>T p.S264= | Silent (SNP) | VAF 209/682 reads (31%) | catalogued as rs755272659, COSV99482210; called by muse, mutect2, varscan2
- CCL8 | c.123G>A p.R41= | Silent (SNP) | VAF 145/449 reads (32%) | catalogued as COSV67013909; called by muse, mutect2, varscan2
- CCR3 | c.825G>A p.R275= | Silent (SNP) | VAF 200/639 reads (31%) | catalogued as rs758890978; called by muse, mutect2, varscan2
- CDKAL1 | c.399C>T p.I133= | Silent (SNP) | VAF 120/472 reads (25%) | catalogued as rs770614347, COSV51192792; called by muse, mutect2, varscan2
- CEACAM20 | c.864C>T p.F288= | Silent (SNP) | VAF 221/723 reads (31%) | called by muse, mutect2, varscan2
- CEACAM21 | c.780C>T p.L260= (on ENST00000401445 / NM_001098506.4; = p.L259= on NM_033543.6) | Silent (SNP) | VAF 170/540 reads (31%) | catalogued as COSV51814229; called by muse, mutect2, varscan2
- CEL | c.2082C>T p.P694= (on ENST00000673714; = p.P691= on NM_001807.6) | Silent (SNP) | VAF 74/188 reads (39%) | catalogued as rs1162171285, COSV60828202; called by muse, varscan2
- CHFR | c.1626T>G p.G542= (on ENST00000432561 / NM_001161345.1; = p.G501= on NM_018223.2) | Silent (SNP) | VAF 78/436 reads (18%) | called by muse, mutect2, varscan2
- CHP1 | c.393C>T p.S131= | Silent (SNP) | VAF 101/341 reads (30%) | catalogued as rs1371512467; called by muse, mutect2, varscan2
- COL28A1 | c.129C>T p.S43= | Silent (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- CRYAB | c.510C>T p.T170= | Silent (SNP) | VAF 39/264 reads (15%) | catalogued as rs147970333, COSV99909912; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD1 | c.2988C>T p.P996= (on ENST00000520002; = p.P995= on NM_033225.6) | Silent (SNP) | VAF 195/660 reads (30%) | catalogued as rs1396332781, COSV59300813, COSV59335872; called by muse, varscan2
- CYP2D7 | c.336C>T p.F112= | Silent (SNP) | VAF 200/664 reads (30%) | catalogued as rs1418591609; called by muse, mutect2, varscan2
- DCC | c.2280C>T p.I760= | Silent (SNP) | VAF 120/537 reads (22%) | catalogued as rs201276568, COSV100499079, COSV59089648; called by muse, mutect2, varscan2
- DEFB104A | c.105C>T p.A35= | Silent (SNP) | VAF 16/120 reads (13%) | called by mutect2, varscan2
- DNAAF1 | c.276C>T p.S92= | Silent (SNP) | VAF 37/251 reads (15%) | called by muse, mutect2, varscan2
- DNAH6 | c.8046G>A p.R2682= | Silent (SNP) | VAF 73/249 reads (29%) | catalogued as COSV52851332; called by muse, mutect2, varscan2
- DOP1B | c.1419C>T p.P473= | Silent (SNP) | VAF 223/532 reads (42%) | catalogued as rs199879429; called by muse, mutect2, varscan2
- EFHB | c.1152G>A p.T384= | Silent (SNP) | VAF 93/326 reads (29%) | catalogued as rs1427596034, COSV55546669; called by muse, mutect2
- EHD3 | c.1092G>A p.Q364= | Silent (SNP) | VAF 118/338 reads (35%) | called by muse, mutect2, varscan2
- EIF3H | c.502A>C p.R168= | Silent (SNP) | VAF 129/368 reads (35%) | called by muse, mutect2, varscan2
- ELL | c.213C>T p.P71= | Silent (SNP) | VAF 187/596 reads (31%) | catalogued as rs367638746; called by muse, mutect2, varscan2
- EPHA8 | c.1782C>T p.F594= | Silent (SNP) | VAF 73/427 reads (17%) | catalogued as rs750902137, COSV51272084; called by muse, mutect2, varscan2
- EXOC4 | c.501C>T p.P167= | Silent (SNP) | VAF 123/348 reads (35%) | called by muse, mutect2, varscan2
- FADS3 | c.1005C>T p.F335= | Silent (SNP) | VAF 130/350 reads (37%) | catalogued as rs111249700, COSV53879798; called by muse, mutect2, varscan2
- FAM187A | c.1065C>T p.F355= | Silent (SNP) | VAF 150/523 reads (29%) | catalogued as rs1406282307; called by muse, mutect2, varscan2
- FLT4 | c.3951G>A p.G1317= | Silent (SNP) | VAF 285/572 reads (50%) | catalogued as COSV99988287; called by muse, mutect2, varscan2
- FOXK2 | c.735G>A p.K245= | Silent (SNP) | VAF 161/496 reads (32%) | called by muse, mutect2, varscan2
- FSIP2 | c.11814C>T p.S3938= | Silent (SNP) | VAF 83/296 reads (28%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.711C>T p.L237= | Silent (SNP) | VAF 208/525 reads (40%) | catalogued as rs768259905, COSV61749107; called by muse, mutect2, varscan2
- GDAP1L1 | c.570G>A p.T190= | Silent (SNP) | VAF 197/565 reads (35%) | catalogued as rs375517198; called by muse, mutect2, varscan2
- GGTLC2 | c.432G>A p.V144= | Silent (SNP) | VAF 133/671 reads (20%) | called by muse, mutect2, varscan2
- GPR26 | c.951C>T p.S317= | Silent (SNP) | VAF 106/507 reads (21%) | catalogued as COSV52933823; called by muse, mutect2, varscan2
- GPR45 | c.699G>A p.S233= | Silent (SNP) | VAF 238/805 reads (30%) | catalogued as rs371966047; called by muse, mutect2, varscan2
- GRM3 | c.576C>T p.P192= | Silent (SNP) | VAF 181/453 reads (40%) | catalogued as rs368299243; called by muse, mutect2, varscan2
- HLA-DQB2 | c.120G>A p.K40= | Silent (SNP) | VAF 482/990 reads (49%) | called by muse, mutect2, varscan2
- HMOX2 | c.243C>T p.L81= | Silent (SNP) | VAF 224/542 reads (41%) | catalogued as rs1295363769; called by muse, varscan2
- HYDIN | c.13833C>T p.I4611= | Silent (SNP) | VAF 48/766 reads (6%) | called by muse, mutect2
- IKZF4 | c.216C>T p.L72= | Silent (SNP) | VAF 181/485 reads (37%) | catalogued as rs778322454; called by muse, mutect2, varscan2
- IL24 | c.351G>A p.L117= | Silent (SNP) | VAF 260/544 reads (48%) | catalogued as COSV54321774; called by muse, mutect2, varscan2
- ILF3 | c.306C>T p.L102= | Silent (SNP) | VAF 208/637 reads (33%) | called by muse, mutect2, varscan2
- ILF3 | c.307C>T p.L103= | Silent (SNP) | VAF 207/639 reads (32%) | called by muse, mutect2, varscan2
- KCNQ3 | c.675C>T p.S225= | Silent (SNP) | VAF 213/631 reads (34%) | catalogued as rs921121642, COSV66480546; called by muse, mutect2, varscan2
- KIAA1549 | c.2910C>T p.I970= | Silent (SNP) | VAF 112/368 reads (30%) | called by muse, mutect2, varscan2
- KLF17 | c.447G>A p.G149= | Silent (SNP) | VAF 115/489 reads (24%) | catalogued as COSV64856990; called by muse, mutect2, varscan2
- KRT20 | c.45C>T p.S15= | Silent (SNP) | VAF 248/717 reads (35%) | called by muse, mutect2, varscan2
- LAMB2 | c.1689C>T p.F563= | Silent (SNP) | VAF 284/830 reads (34%) | called by muse, mutect2, varscan2
- LGI1 | c.1488C>T p.Y496= | Silent (SNP) | VAF 62/232 reads (27%) | called by muse, mutect2, varscan2
- LIMS1 | c.69C>T p.I23= | Silent (SNP) | VAF 254/1279 reads (20%) | catalogued as rs375236817; called by muse, mutect2, varscan2
- LPIN3 | c.525C>T p.S175= | Silent (SNP) | VAF 136/481 reads (28%) | called by muse, mutect2, varscan2
- MACC1 | c.1776C>T p.S592= | Silent (SNP) | VAF 98/367 reads (27%) | catalogued as rs1402895358; called by muse, mutect2, varscan2
- MARCHF10 | c.681C>T p.S227= | Silent (SNP) | VAF 203/631 reads (32%) | called by muse, mutect2, varscan2
- MB21D2 | c.1137C>T p.I379= | Silent (SNP) | VAF 226/615 reads (37%) | catalogued as rs777147620; called by muse, mutect2, varscan2
- MICALL1 | c.378C>T p.S126= | Silent (SNP) | VAF 128/403 reads (32%) | called by muse, mutect2, varscan2
- MORC1 | c.369G>A p.T123= | Silent (SNP) | VAF 61/241 reads (25%) | catalogued as rs373682179; called by muse, mutect2, varscan2
- MRPS12 | c.352C>T p.L118= | Silent (SNP) | VAF 182/552 reads (33%) | called by muse, varscan2
- MUC16 | c.21657G>A p.E7219= | Silent (SNP) | VAF 179/459 reads (39%) | called by muse, mutect2, varscan2
- MUC16 | c.21210G>A p.E7070= | Silent (SNP) | VAF 145/483 reads (30%) | catalogued as rs774903170, COSV101202126; called by muse, mutect2, varscan2
- MUC16 | c.11898C>T p.S3966= | Silent (SNP) | VAF 203/618 reads (33%) | catalogued as COSV101201500; called by muse, mutect2
- MUC16 | c.1281G>A p.K427= | Silent (SNP) | VAF 185/530 reads (35%) | catalogued as rs751891780; called by muse, mutect2, varscan2
- MYH1 | c.48C>T p.F16= | Silent (SNP) | VAF 139/451 reads (31%) | called by muse, mutect2, varscan2
- MYH15 | c.4815C>T p.T1605= | Silent (SNP) | VAF 104/342 reads (30%) | called by muse, mutect2, varscan2
- MYH4 | c.4794G>A p.V1598= | Silent (SNP) | VAF 156/472 reads (33%) | called by muse, varscan2
- NGF | c.42C>T p.I14= | Silent (SNP) | VAF 246/476 reads (52%) | catalogued as rs752800027, COSV65687643; called by muse, mutect2, varscan2
- NLRP5 | c.957C>T p.L319= | Silent (SNP) | VAF 189/600 reads (32%) | called by muse, mutect2, varscan2
- NLRP7 | c.1395C>T p.S465= | Silent (SNP) | VAF 300/1065 reads (28%) | catalogued as COSV60176915; called by muse, mutect2, varscan2
- NOS2 | c.696T>C p.R232= | Silent (SNP) | VAF 193/656 reads (29%) | called by muse, mutect2
- NPAP1 | c.285G>A p.R95= | Silent (SNP) | VAF 301/957 reads (31%) | catalogued as COSV61510930; called by muse, mutect2, varscan2
- NPAP1 | c.2154G>A p.K718= | Silent (SNP) | VAF 224/654 reads (34%) | catalogued as COSV100275159; called by muse, mutect2, varscan2
- NPHS1 | c.3579C>T p.Y1193= | Silent (SNP) | VAF 106/312 reads (34%) | catalogued as rs747950877, COSV62286104; called by muse, mutect2, varscan2
- NPPA | c.402G>A p.R134= | Silent (SNP) | VAF 94/558 reads (17%) | called by muse, mutect2, varscan2
- NUF2 | c.498G>A p.L166= | Silent (SNP) | VAF 150/304 reads (49%) | catalogued as rs1467454730; called by muse, mutect2, varscan2
- OBSCN | c.480G>A p.V160= | Silent (SNP) | VAF 115/619 reads (19%) | called by muse, mutect2, varscan2
- OPRD1 | c.75C>T p.S25= | Silent (SNP) | VAF 94/849 reads (11%) | called by muse, mutect2
- OR10A7 | c.603C>T p.A201= | Silent (SNP) | VAF 73/339 reads (22%) | called by muse, mutect2, varscan2
- OR1B1 | c.810C>T p.F270= | Silent (SNP) | VAF 123/313 reads (39%) | called by muse, mutect2
- OR4D5 | c.745T>C p.L249= | Silent (SNP) | VAF 77/488 reads (16%) | called by muse, mutect2, varscan2
- OR4K13 | c.444C>T p.S148= | Silent (SNP) | VAF 159/455 reads (35%) | catalogued as COSV100237746; called by muse, mutect2, varscan2
- OR4L1 | c.888G>A p.E296= | Silent (SNP) | VAF 51/197 reads (26%) | catalogued as rs1333713171; called by muse, mutect2
- OR51M1 | c.381C>T p.L127= | Silent (SNP) | VAF 51/469 reads (11%) | catalogued as rs776328978, COSV60785050; called by muse, mutect2, varscan2
- OR6Y1 | c.723G>A p.K241= | Silent (SNP) | VAF 263/557 reads (47%) | catalogued as rs887909279; called by muse, mutect2, varscan2
- OR8D2 | c.771C>T p.F257= | Silent (SNP) | VAF 34/310 reads (11%) | called by muse, mutect2, varscan2
- OR9H1P | c.321C>T p.I107= | Silent (SNP) | VAF 82/469 reads (17%) | called by muse, mutect2, varscan2
- OVGP1 | c.822G>A p.K274= | Silent (SNP) | VAF 281/559 reads (50%) | called by muse, mutect2, varscan2
- P2RY10 | c.729G>A p.R243= | Silent (SNP) | VAF 243/367 reads (66%) | catalogued as rs1382166632; called by muse, mutect2, varscan2
- PAK5 | c.1011G>A p.Q337= | Silent (SNP) | VAF 115/589 reads (20%) | catalogued as COSV62031382; called by muse, mutect2, varscan2
- PAQR9 | c.720C>T p.F240= | Silent (SNP) | VAF 274/801 reads (34%) | catalogued as rs758925968; called by muse, mutect2, varscan2
- PHKG1 | c.909G>A p.G303= | Silent (SNP) | VAF 128/418 reads (31%) | catalogued as rs1051312547; called by muse, mutect2, varscan2
- PHLPP2 | c.3390G>A p.Q1130= | Silent (SNP) | VAF 116/500 reads (23%) | called by muse, mutect2, varscan2
- PLCG2 | c.1788C>T p.T596= | Silent (SNP) | VAF 253/634 reads (40%) | called by muse, mutect2, varscan2
- POTEE | c.2859G>A p.E953= | Silent (SNP) | VAF 240/1948 reads (12%) | catalogued as rs1490114091; called by muse, mutect2
- PSG1 | c.9C>T p.T3= | Silent (SNP) | VAF 114/411 reads (28%) | catalogued as COSV54944119; called by muse, mutect2, varscan2
- PSME4 | c.4897T>C p.L1633= | Silent (SNP) | VAF 76/224 reads (34%) | called by muse, mutect2, varscan2
- PTPN20 | c.30G>A p.E10= | Silent (SNP) | VAF 75/1202 reads (6%) | called by muse, mutect2
- PTPRN2 | c.1761G>A p.L587= | Silent (SNP) | VAF 67/399 reads (17%) | catalogued as COSV67027970; called by muse, mutect2, varscan2
- PXDN | c.3651C>G p.L1217= | Silent (SNP) | VAF 179/568 reads (32%) | called by muse, mutect2, varscan2
- RECQL4 | c.3102C>A p.A1034= | Silent (SNP) | VAF 133/856 reads (16%) | called by muse, mutect2, varscan2
- REXO5 | c.1413C>T p.P471= | Silent (SNP) | VAF 134/329 reads (41%) | called by muse, mutect2, varscan2
- RNPS1 | c.843C>T p.S281= | Silent (SNP) | VAF 186/489 reads (38%) | catalogued as rs1249256274; called by muse, mutect2, varscan2
- RYR3 | c.888C>T p.A296= | Silent (SNP) | VAF 188/531 reads (35%) | called by muse, mutect2, varscan2
- RYR3 | c.4584C>T p.P1528= | Silent (SNP) | VAF 242/697 reads (35%) | catalogued as rs1451632299, COSV66778911; called by muse, varscan2
- RYR3 | c.10953G>A p.G3651= (on ENST00000389232; = p.G3652= on NM_001036.6) | Silent (SNP) | VAF 178/537 reads (33%) | called by muse, mutect2, varscan2
- RYR3 | c.11694G>T p.L3898= (on ENST00000389232; = p.L3899= on NM_001036.6) | Silent (SNP) | VAF 124/334 reads (37%) | called by muse, mutect2, varscan2
- S100A14 | c.306G>A p.R102= | Silent (SNP) | VAF 191/363 reads (53%) | catalogued as rs1193108582; called by muse, mutect2, varscan2
- SBK3 | c.720C>T p.F240= | Silent (SNP) | VAF 251/866 reads (29%) | called by muse, mutect2, varscan2
- SBK3 | c.348C>T p.F116= | Silent (SNP) | VAF 250/758 reads (33%) | catalogued as rs992484346; called by muse, mutect2, varscan2
- SCFD2 | c.1302C>T p.L434= | Silent (SNP) | VAF 95/327 reads (29%) | called by muse, mutect2, varscan2
- SEMA3E | c.1923C>T p.F641= | Silent (SNP) | VAF 78/361 reads (22%) | catalogued as COSV57090640; called by muse, mutect2, varscan2
- SFMBT2 | c.825C>T p.S275= | Silent (SNP) | VAF 80/310 reads (26%) | called by muse, mutect2, varscan2
- SGCA | c.1065G>A p.R355= | Silent (SNP) | VAF 305/924 reads (33%) | catalogued as rs1341399668; called by muse, mutect2, varscan2
- SH3D19 | c.1863C>T p.P621= | Silent (SNP) | VAF 120/497 reads (24%) | called by muse, mutect2, varscan2
- SH3TC1 | c.3153C>T p.D1051= | Silent (SNP) | VAF 122/448 reads (27%) | catalogued as rs373577257; called by muse, mutect2, varscan2
- SI | c.3309G>A p.S1103= | Silent (SNP) | VAF 112/360 reads (31%) | catalogued as rs765589827, COSV100017295; called by muse, mutect2, varscan2
- SIGLECL1 | c.45C>T p.S15= | Silent (SNP) | VAF 102/341 reads (30%) | called by muse, mutect2, varscan2
- SIRT1 | c.681C>T p.I227= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as COSV99281650; called by muse, mutect2, varscan2
- SLC13A2 | c.1008C>T p.F336= | Silent (SNP) | VAF 243/698 reads (35%) | catalogued as rs868952819, COSV58993921; called by muse, mutect2, varscan2
- SLC35F2 | c.375C>T p.I125= | Silent (SNP) | VAF 83/267 reads (31%) | catalogued as rs773395067, COSV56183080; called by muse, mutect2, varscan2
- SLC41A2 | c.1545C>T p.T515= | Silent (SNP) | VAF 41/254 reads (16%) | catalogued as COSV51605911, COSV99316767; called by muse, mutect2, varscan2
- SLC6A2 | c.1362C>T p.F454= | Silent (SNP) | VAF 140/312 reads (45%) | called by muse, mutect2, varscan2
- SLC6A3 | c.216C>T p.S72= | Silent (SNP) | VAF 343/749 reads (46%) | catalogued as rs373050350; called by muse, mutect2, varscan2
- SLC7A14 | c.1824C>T p.I608= | Silent (SNP) | VAF 199/673 reads (30%) | called by muse, mutect2, varscan2
- SLC7A8 | c.1248C>T p.I416= | Silent (SNP) | VAF 164/526 reads (31%) | catalogued as rs753488263, COSV57552902; called by muse, mutect2, varscan2
- SLIT3 | c.1644G>A p.E548= | Silent (SNP) | VAF 167/324 reads (52%) | called by muse, mutect2, varscan2
- SNX29 | c.801C>T p.I267= | Silent (SNP) | VAF 139/343 reads (41%) | called by muse, mutect2, varscan2
- SPHKAP | c.609G>A p.T203= | Silent (SNP) | VAF 158/571 reads (28%) | catalogued as rs1246576109, COSV60869524; called by muse, mutect2, varscan2
- SRC | c.1096C>T p.L366= | Silent (SNP) | VAF 217/594 reads (37%) | called by muse, mutect2, varscan2
- SRGAP3 | c.3132C>T p.S1044= | Silent (SNP) | VAF 328/959 reads (34%) | catalogued as rs748187826; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRPK1 | c.879G>A p.E293= | Silent (SNP) | VAF 172/737 reads (23%) | called by muse, mutect2, varscan2
- STK38 | c.408G>A p.A136= | Silent (SNP) | VAF 111/532 reads (21%) | catalogued as rs1429746464; called by muse, mutect2, varscan2
- SUN5 | c.438G>A p.E146= | Silent (SNP) | VAF 140/419 reads (33%) | called by muse, mutect2, varscan2
- SV2A | c.288G>A p.G96= | Silent (SNP) | VAF 428/831 reads (52%) | called by muse, mutect2, varscan2
- TAF1C | c.1623C>T p.D541= | Silent (SNP) | VAF 193/522 reads (37%) | catalogued as rs767803386; called by muse, mutect2, varscan2
- TAF3 | c.525C>T p.F175= | Silent (SNP) | VAF 66/326 reads (20%) | catalogued as rs1175864993; called by muse, varscan2
- TAS2R39 | c.222G>A p.R74= | Silent (SNP) | VAF 64/415 reads (15%) | catalogued as COSV101489413; called by muse, mutect2, varscan2
- TAS2R41 | c.672C>T p.P224= | Silent (SNP) | VAF 218/581 reads (38%) | called by muse, mutect2, varscan2
- TBC1D10C | c.768C>T p.F256= | Silent (SNP) | VAF 72/656 reads (11%) | catalogued as COSV56705195; called by muse, mutect2, varscan2
- TELO2 | c.1095C>T p.L365= | Silent (SNP) | VAF 291/766 reads (38%) | catalogued as rs780757073; called by muse, mutect2, varscan2
- TENM4 | c.6363G>A p.G2121= | Silent (SNP) | VAF 162/439 reads (37%) | catalogued as rs779128065; called by muse, mutect2, varscan2
- TFAP4 | c.210C>T p.S70= | Silent (SNP) | VAF 100/511 reads (20%) | catalogued as COSV52597876; called by muse, mutect2, varscan2
- TMC2 | c.1539C>T p.F513= | Silent (SNP) | VAF 126/611 reads (21%) | catalogued as COSV62656386; called by muse, mutect2, varscan2
- TMEM265 | c.195C>T p.S65= | Silent (SNP) | VAF 130/640 reads (20%) | catalogued as rs1458227412; called by muse, mutect2, varscan2
- TRAPPC12 | c.780C>T p.P260= | Silent (SNP) | VAF 324/898 reads (36%) | catalogued as rs1350381543, COSV60852740; called by muse, mutect2, varscan2
- TRERF1 | c.1599C>T p.S533= | Silent (SNP) | VAF 350/766 reads (46%) | called by muse, mutect2, varscan2
- TTC28 | c.2559C>T p.A853= | Silent (SNP) | VAF 217/667 reads (33%) | called by muse, mutect2, varscan2
- TTC28 | c.1182C>T p.A394= | Silent (SNP) | VAF 248/751 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.16245C>T p.F5415= (on ENST00000591111; = p.F4488= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/344 reads (25%) | catalogued as COSV100596679; called by muse, mutect2, varscan2
- TXLNB | c.1500G>A p.V500= | Silent (SNP) | VAF 208/435 reads (48%) | catalogued as rs973437196, COSV64443574; called by muse, mutect2, varscan2
- TXNDC2 | c.951C>T p.S317= (on ENST00000306084 / NM_001098529.2; = p.S250= on NM_032243.6) | Silent (SNP) | VAF 142/795 reads (18%) | called by muse, mutect2, varscan2
- UPK3BL2 | c.178C>T p.L60= | Silent (SNP) | VAF 74/916 reads (8%) | called by muse, mutect2
- UQCC1 | c.246C>T p.S82= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as COSV62902011; called by muse, mutect2, varscan2
- USP6 | c.2064A>G p.Q688= | Silent (SNP) | VAF 155/427 reads (36%) | called by muse, mutect2, varscan2
- VWA3B | c.2730C>T p.P910= | Silent (SNP) | VAF 190/528 reads (36%) | called by muse, mutect2, varscan2
- WDFY4 | c.1371C>T p.F457= | Silent (SNP) | VAF 118/494 reads (24%) | catalogued as rs767767458, COSV57428372; called by muse, mutect2, varscan2
- XIRP2 | c.9450C>T p.F3150= (on ENST00000628543; = p.F3325= on NM_152381.6) | Silent (SNP) | VAF 130/432 reads (30%) | catalogued as rs1553505593, COSV54686043, COSV54714181; called by muse, mutect2, varscan2
- ZAN | c.2913C>T p.I971= | Silent (SNP) | VAF 302/750 reads (40%) | catalogued as rs772624007; called by muse, mutect2, varscan2
- ZNF331 | c.1308G>A p.A436= | Silent (SNP) | VAF 135/432 reads (31%) | catalogued as rs757099778, COSV53480824; called by muse, mutect2, varscan2
- ZNF589 | c.243C>T p.V81= | Silent (SNP) | VAF 103/324 reads (32%) | catalogued as rs1463475370; called by muse, mutect2, varscan2
- ZNF628 | c.2718C>T p.P906= | Silent (SNP) | VAF 228/932 reads (24%) | catalogued as rs1471532524; called by muse, mutect2, varscan2
- ZNF764 | c.1098G>A p.R366= | Silent (SNP) | VAF 193/944 reads (20%) | called by muse, mutect2, varscan2
- ZNF781 | c.414C>T p.F138= | Silent (SNP) | VAF 102/346 reads (29%) | catalogued as COSV62202279; called by muse, mutect2, varscan2
- ZNF836 | c.522T>C p.S174= | Silent (SNP) | VAF 65/196 reads (33%) | called by muse, mutect2, varscan2
- ZZEF1 | c.1761T>C p.I587= | Silent (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- AC010542.3 | c.149-12099C>T | Intron (SNP) | VAF 118/622 reads (19%) | called by muse, mutect2, varscan2
- ASF1B | c.402+20C>T | Intron (SNP) | VAF 228/714 reads (32%) | catalogued as rs551592911; called by muse, mutect2, varscan2
- CASR | c.1378-6094C>T | Intron (SNP) | VAF 89/328 reads (27%) | called by muse, mutect2, varscan2
- CSMD3 | c.*1647C>T | 3'UTR (SNP) | VAF 64/147 reads (44%) | called by muse, mutect2, varscan2
- DNAH10 | c.13307-475G>A | Intron (SNP) | VAF 107/499 reads (21%) | called by muse, mutect2, varscan2
- ENAH | c.803-543C>T | Intron (SNP) | VAF 24/460 reads (5%) | called by muse, mutect2
- GFM1 | c.689+847G>A | Intron (SNP) | VAF 116/445 reads (26%) | called by muse, mutect2, varscan2
- GHDC | c.1289-78A>G | Intron (SNP) | VAF 130/440 reads (30%) | called by muse, mutect2, varscan2
- GRIK3 | c.2565+47C>T | Intron (SNP) | VAF 232/620 reads (37%) | catalogued as rs776657718, COSV100901710; called by muse, mutect2, varscan2
- HSPB7 | chr1:16019230 C>T | 5'Flank (SNP) | VAF 240/635 reads (38%) | catalogued as COSV58893453; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+19707G>A | Intron (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2
- MUCL3 | c.947-991G>A | Intron (SNP) | VAF 287/1095 reads (26%) | called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442963 T>A | 3'Flank (SNP) | VAF 97/273 reads (36%) | called by muse, mutect2, varscan2
- NEB | c.11601+6132C>T | Intron (SNP) | VAF 200/1212 reads (17%) | called by muse, mutect2, varscan2
- PENK | c.138+1842C>T | Intron (SNP) | VAF 113/391 reads (29%) | called by muse, mutect2, varscan2
- RAD23B | c.*2052C>T | 3'UTR (SNP) | VAF 135/301 reads (45%) | catalogued as rs1157127438; called by muse, mutect2, varscan2
- REXO1L1P | chr8:85663444 C>T | 5'Flank (SNP) | VAF 32/1386 reads (2%) | called by muse, mutect2
- TRIB2 | c.563+1180A>C | Intron (SNP) | VAF 188/603 reads (31%) | called by mutect2, varscan2
- TTN | c.34354+576A>T | Intron (SNP) | VAF 124/418 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.10360+1678G>A | Intron (SNP) | VAF 95/290 reads (33%) | catalogued as rs1304491491; called by muse, mutect2, varscan2
- TXNRD3 | n.516G>A | RNA (SNP) | VAF 183/609 reads (30%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26672741 G>A | 3'Flank (SNP) | VAF 178/499 reads (36%) | called by muse, mutect2, varscan2
